Somatic mutation profile of tumor specimen TCGA-B0-5702-01A (aliquot TCGA-B0-5702-01A-11D-1534-10) from TCGA case TCGA-B0-5702, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.7 years (26,186 days).
Specimen TCGA-B0-5702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12d47ab4-b068-4e15-ba06-e47ad23768f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5702-11A (Solid Tissue Normal), aliquot TCGA-B0-5702-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8395409-6f6e-4c27-afe5-62cf38d0328c

The open-access MAF lists 66 somatic variants for this specimen: 56 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 8, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV61249062; called by muse, mutect2, varscan2
- ATF7IP | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.295); catalogued as COSV53765618; called by muse, mutect2, varscan2
- BRPF3 | c.1760T>C p.M587T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV60205611; called by muse, mutect2, varscan2
- CABIN1 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.349); catalogued as COSV54076906; called by muse, mutect2
- CCKBR | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV58098316; called by muse, mutect2, varscan2
- CENPE | c.5473C>A p.L1825I | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54375373; called by muse, mutect2
- CEP63 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV59674153; called by muse, mutect2
- CLVS1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.097); catalogued as COSV57969879; called by muse, mutect2
- CMTR2 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs559412558, COSV57602357; called by muse, mutect2, varscan2
- CSMD3 | c.4342G>T p.D1448Y (on ENST00000297405 / NM_001363185.1; = p.D1344Y on NM_052900.3) | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs758281787, COSV52090534, COSV52257724, COSV52306319; called by muse, mutect2
- CSRNP1 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.215); catalogued as COSV56186983; called by muse, mutect2, varscan2
- EEA1 | c.2325A>T p.E775D | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59282049; called by muse, mutect2, varscan2
- FILIP1 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52722115; called by muse, mutect2
- FLG2 | c.6184G>T p.G2062* | Nonsense Mutation (SNP) | VAF 61/485 reads (13%) | catalogued as COSV66166261; called by muse, mutect2, varscan2
- FLG2 | c.3521G>A p.G1174D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs767902362, COSV66166267, COSV66168862; called by muse, mutect2, varscan2
- FRMPD4 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66210793; called by muse, mutect2, varscan2
- GALNT5 | c.2533A>C p.N845H | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52035539; called by muse, mutect2, varscan2
- GATAD2B | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 22/549 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64082986; called by muse, mutect2
- GCNA | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV65465665; called by muse, mutect2, varscan2
- GJD2 | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51746953; called by muse, mutect2
- IGDCC3 | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as COSV60076227; called by muse, mutect2
- KLHDC1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV63778281; called by muse, mutect2, varscan2
- KRT7 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | catalogued as COSV59329244, COSV59333698; called by muse, mutect2, varscan2
- LAMA3 | c.8311T>C p.S2771P (on ENST00000313654 / NM_198129.4; = p.S1162P on NM_000227.6) | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52528917; called by muse, varscan2
- LAMC2 | c.1316A>T p.D439V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV51451965; called by muse, mutect2, varscan2
- NBR1 | c.1396C>A p.Q466K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV57830383; called by muse, mutect2, varscan2
- NPFFR2 | c.905C>G p.T302S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as COSV100441211, COSV58145745; called by muse, mutect2
- NRROS | c.633C>A p.N211K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV60744499; called by muse, mutect2, varscan2
- OR52I1 | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56167246; called by muse, varscan2
- P2RY8 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67176648; called by muse, mutect2, varscan2
- PARD6B | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs768668443, COSV65404029; called by muse, mutect2, varscan2
- PCF11 | c.1380A>G p.I460M | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53526907; called by muse, mutect2
- PHKB | c.2373A>C p.K791N | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54513025; called by muse, mutect2, varscan2
- PIGO | c.2783A>C p.H928P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53052282; called by muse, mutect2, varscan2
- PLA2G4C | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV62783710; called by muse, mutect2, varscan2
- PPARG | c.491G>A p.R164Q (on ENST00000287820 / NM_015869.5; = p.R134Q on NM_005037.7) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55140645; called by muse, mutect2, varscan2
- PRCC | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV54854657; called by muse, mutect2, varscan2
- PRKCSH | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV52950056; called by muse, mutect2
- PSD3 | c.2866G>T p.D956Y (on ENST00000440756; = p.D955Y on NM_015310.4) | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1225938318, COSV54065578; called by muse, mutect2, varscan2
- RAI2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518314; called by muse, mutect2
- REEP4 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as COSV57941338; called by muse, mutect2
- RRM1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV56162649; called by muse, mutect2, varscan2
- RYR2 | c.10611G>T p.R3537S | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV63657288; called by muse, mutect2
- SAMHD1 | c.1588G>A p.A530T (on ENST00000262878 / NM_001363729.2; = p.A565T on NM_015474.4) | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs779491090, CM150578, COSV53428046, COSV53431969; called by muse, mutect2
- SCMH1 | c.298G>A p.D100N (on ENST00000326197 / NM_001031694.2; = p.D53N on NM_012236.4) | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58231770; called by muse, mutect2
- SHOC1 | c.2176T>A p.L726M | Missense Mutation (SNP) | VAF 22/826 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59497105; called by muse, mutect2
- SLC9A7 | c.812T>G p.F271C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60377260; called by muse, mutect2, varscan2
- TATDN1 | c.37T>G p.L13V | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52677317; called by muse, mutect2, varscan2
- TCEAL3 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV54579984; called by muse, mutect2, varscan2
- XPNPEP3 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63210036; called by muse, mutect2, varscan2
- XPO7 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs576438786, COSV53010321; called by muse, mutect2, varscan2
- CSMD3 | c.2400del p.T801Lfs*52 (on ENST00000297405 / NM_001363185.1; = p.T697Lfs*52 on NM_052900.3) | Frame Shift Del (DEL) | VAF 15/171 reads (9%) | called by mutect2, pindel
- HSD17B2 | c.265+1del | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- MORC4 | c.180dup p.A61Cfs*16 | Frame Shift Ins (INS) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- SETD2 | c.2004del p.I669* | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- USP15 | c.782_783insT p.N262Kfs*11 (on ENST00000280377 / NM_001351159.2; = p.N233Kfs*11 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 30/224 reads (13%) | called by mutect2, pindel*, varscan2
- BBS10 | c.1608T>C p.Y536= | Silent (SNP) | VAF 36/428 reads (8%) | catalogued as COSV67913007; called by muse, mutect2
- BRDT | c.2523G>A p.R841= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV62863000; called by muse, mutect2
- COL24A1 | c.2784A>C p.S928= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as COSV65300969; called by muse, mutect2, varscan2
- DHRS13 | c.930G>A p.L310= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV66683754; called by muse, varscan2
- FBXO11 | c.1506T>A p.T502= (on ENST00000403359 / NM_001190274.2; = p.T418= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/553 reads (10%) | catalogued as COSV57015555; called by muse, mutect2, varscan2
- KCNU1 | c.3004C>A p.R1002= | Silent (SNP) | VAF 46/436 reads (11%) | catalogued as rs772507751, COSV67752553; called by muse, mutect2, varscan2
- PARP1 | c.2067T>C p.Y689= | Silent (SNP) | VAF 40/362 reads (11%) | catalogued as COSV64689040; called by muse, varscan2
- TEX14 | c.2043C>A p.G681= (on ENST00000240361 / NM_001201457.2; = p.G675= on NM_031272.5) | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as COSV53610931; called by muse, mutect2
- CARD19 | c.*1173T>A | 3'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as COSV64935762; called by muse, mutect2, varscan2
- RTL1 | chr14:100875044 G>T | 3'Flank (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
